Surgical pathology report (de-identified scan), TCGA case TCGA-XS-A8TJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-XS-A8TJ-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell non-
keratinizing NOS 8072/3
Site: Cervix NOS C53.9
JW 1/29/14

Nature of material: Cervix

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Specimen consists of the uterus and left fallopian tube, weighing 559.0 grams. The tube measures 9.0 cm in length and diameter ranges between 6.0 and 1.5 cm. To the cuts, the wall is thin, measuring 0.1 cm, the light is dilated and filled with hemorrhagic content. The uterus measures 13.5 cm in its longitudinal axis, 8.0 cm in anteroposterior diameter and 8.5 cm in bicornal distance. The cervix measures 3.7 cm in diameter and is surrounded by the vaginal dome, measuring between 0.7 and 1.2 cm. It is observed hard and ulcerated lesion with poorly defined edges and granular background, measuring 3.4 x 3.0 cm, involving all quadrants of the cervix. To the cuts, the myometrium measures 7.8 cm at the bottom, which is thicker, and it has multiple round, firm and whitish lesions, with crisscrossing beams. The endometrium measures 0.4 cm.

MICROSCOPY

Dispensable description.

DIAGNOSTIC

Product of hysterectomy and left salpingectomy:

- Invasive squamous cell carcinoma, non-keratinizing, moderately differentiated, measuring 3.4 x 3.0 cm in major axis and infiltrating the stroma until 1.38 cm in depth and 2.8 cm in horizontal extent, without compromising uterine isthmus or circumferential and vaginal resection margins.
- Presence of extensive component by squamous cell carcinoma in situ.
- Presence of neoplastic lymphatic embolization.
- Uterine leiomyomas.
- Endometriosis in parametrium bilaterally and in the left fallopian tube.
- Dysfunctional endometrium with moderate stromal edema.
- Pathological staging: pT1b1, pN1 (TNM 7th).
- For lymph node biopsy, see biopsy number in this service.

Source: NCI Genomic Data Commons file 00103fa2-43e4-4c6a-babb-d8b46612399e (TCGA-XS-A8TJ.C8BBFFAA-4A45-44D3-921B-6F2BD8DB5B19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).